Somatic mutation profile of tumor specimen TCGA-C5-A7X5-01A (aliquot TCGA-C5-A7X5-01A-11D-A36J-09) from TCGA case TCGA-C5-A7X5, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 72.7 years (26,542 days).
Specimen TCGA-C5-A7X5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0a36fc5-6ee7-47d0-9a57-09d1f49e23fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A7X5-10A (Blood Derived Normal), aliquot TCGA-C5-A7X5-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a29cc91-73ae-4a97-a852-303de3cb1571

The open-access MAF lists 255 somatic variants for this specimen: 178 protein-altering or splice-affecting, 71 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 156, Silent 71, Nonsense Mutation 13, Splice Region 4, Intron 3, RNA 2, Frame Shift Del 2, Frame Shift Ins 1, 5'Flank 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGF3 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 59/67 reads (88%) | catalogued as rs121917704, CM070117, COSV100490202; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 81/135 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99710498; called by muse, mutect2, varscan2
- ACTG2 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV100608851, COSV100609206; called by muse, mutect2, varscan2
- ACTN4 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1004686336, COSV99400252; called by muse, mutect2, varscan2
- ADIRF | c.164A>T p.D55V | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100920974; called by muse, mutect2, varscan2
- AIFM1 | c.859-1G>A p.X287_splice | Splice Site (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99781050, COSV99781190; called by muse, mutect2, varscan2
- AKIRIN2 | c.608C>A p.S203* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100005212; called by muse, mutect2, varscan2
- ANAPC1 | c.4615T>C p.C1539R | Missense Mutation (SNP) | VAF 248/349 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV100594749; called by muse, mutect2, varscan2
- ASB10 | c.1064A>T p.N355I (on ENST00000420175 / NM_001142459.2; = p.N340I on NM_080871.4) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99318630; called by muse, mutect2, varscan2
- BGN | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs933381952, COSV59036240; called by muse, mutect2, varscan2
- BMS1 | c.2140G>A p.G714R | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1337423246, COSV100996714; called by muse, mutect2, varscan2
- BRWD3 | c.2051G>T p.R684I | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100956098; called by muse, mutect2, varscan2
- BTNL9 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 25/62 reads (40%) | catalogued as COSV59795932; called by muse, mutect2, varscan2
- CAPSL | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs368551299, COSV68438743; called by muse, mutect2, varscan2
- CARMIL1 | c.2443C>T p.R815C | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as rs1432033154, COSV100277910; called by muse, mutect2, varscan2
- CCDC14 | c.1279C>T p.P427S (on ENST00000488653; = p.P379S on NM_022757.5) | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.415); catalogued as COSV100113231; called by muse, mutect2, varscan2
- CD180 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 31/89 reads (35%) | catalogued as COSV99842257; called by muse, mutect2, varscan2
- CD1B | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.294); catalogued as COSV100939238; called by muse, mutect2, varscan2
- CD1E | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs372577196; called by muse, mutect2, varscan2
- CDH4 | c.2548C>T p.L850F | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848935; called by muse, mutect2, varscan2
- CEP162 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100002842; called by muse, mutect2, varscan2
- CEP57 | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100334718; called by muse, mutect2, varscan2
- CFHR4 | c.191G>A p.G64E (on ENST00000367416 / NM_001201551.2; = p.G65E on NM_006684.5) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.807); catalogued as COSV52236032; called by muse, mutect2, varscan2
- CNTN1 | c.1806C>T p.G602= | Splice Region (SNP) | VAF 12/109 reads (11%) | catalogued as COSV100751435; called by muse, mutect2, varscan2
- COL19A1 | c.2360G>A p.R787K | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV59565720; called by muse, mutect2, varscan2
- COLGALT2 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV100730681; called by muse, mutect2
- CORO1A | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs1028173314, COSV99531796; called by muse, mutect2, varscan2
- CPNE4 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753178143, COSV70192655; called by muse, mutect2, varscan2
- CSMD1 | c.2302G>A p.G768R (on ENST00000520002; = p.G767R on NM_033225.6) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59313228; called by muse, mutect2, varscan2
- CUL3 | c.124C>G p.Q42E | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.803); catalogued as COSV100024274, COSV52367909; called by muse, mutect2, varscan2
- CYRIA | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV100838405; called by muse, mutect2, varscan2
- DGKH | c.2456G>C p.R819T | Missense Mutation (SNP) | VAF 55/226 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99818871; called by muse, mutect2, varscan2
- DLL3 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752084828, COSV99219113; called by muse, mutect2
- DMXL1 | c.8329C>G p.Q2777E | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV100224014, COSV100225269; called by muse, mutect2, varscan2
- DNAH9 | c.10447G>A p.D3483N | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99305980; called by muse, mutect2, varscan2
- DOCK7 | c.2959G>A p.E987K (on ENST00000635253 / NM_001367561.1; = p.E956K on NM_033407.3) | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs540487612, COSV52001463; ClinVar: uncertain significance; called by muse, mutect2
- DOP1A | c.1658G>A p.G553E | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.054); catalogued as rs1051619675, COSV99381989; called by muse, mutect2, varscan2
- DUS4L | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.117); catalogued as COSV99143660; called by muse, mutect2, varscan2
- DVL3 | c.351C>T p.F117= | Splice Region (SNP) | VAF 23/138 reads (17%) | catalogued as COSV100493668; called by muse, mutect2, varscan2
- EDRF1 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.147); catalogued as COSV100523506; called by muse, mutect2, varscan2
- EGFLAM | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.037); catalogued as rs267600618, COSV59316379; called by muse, mutect2, varscan2
- EIF4G1 | c.3634G>A p.E1212K (on ENST00000346169 / NM_198241.3; = p.E1017K on NM_004953.5) | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV59995725; called by muse, mutect2, varscan2
- ERAS | c.251T>G p.L84R | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV99504835; called by muse, mutect2, varscan2
- EZH1 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as COSV70548771, COSV70550164; called by muse, mutect2, varscan2
- EZHIP | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs782524965, COSV100539730; called by muse, mutect2, varscan2
- F5 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100889115; called by muse, mutect2, varscan2
- FAH | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs1284184976, COSV99930304; called by muse, mutect2, varscan2
- FAM47C | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.664); catalogued as rs782247630, COSV63727798; called by muse, mutect2, varscan2
- FMO4 | c.978C>A p.F326L | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV100882061; called by muse, mutect2
- FSCB | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.791); catalogued as COSV100469364; called by muse, mutect2, varscan2
- FZD10 | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV57475823, COSV99969440; called by muse, mutect2, varscan2
- GATAD2A | c.883G>C p.A295P | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV99390230; called by muse, mutect2, varscan2
- GIMAP8 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs1403308914, COSV56235163; called by muse, mutect2, varscan2
- GMPPB | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV100246598; called by muse, mutect2, varscan2
- GMPPB | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100246599; called by muse, varscan2
- GMPPB | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1231333069, COSV57538102; called by muse, mutect2, varscan2
- GNAS | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.982); catalogued as COSV99670121; called by muse, mutect2, varscan2
- GSDMC | c.206G>A p.S69N | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.145); catalogued as rs1442125447, COSV99416021; called by muse, mutect2, varscan2
- GSN | c.1924T>C p.W642R | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100376225; called by muse, varscan2
- GTF2IRD1 | c.2495G>A p.R832Q (on ENST00000265755 / NM_016328.3; = p.R817Q on NM_005685.4) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.523); catalogued as rs781925026, COSV56087796; called by muse, mutect2, varscan2
- H4C2 | c.166C>G p.R56G | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs553183619, COSV99774957; called by muse, mutect2, varscan2
- HAS1 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs554437003, COSV99708421; called by muse, mutect2, varscan2
- HEATR5B | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs757089586, COSV51851950; called by muse, mutect2, varscan2
- HORMAD1 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as COSV100464187; called by muse, mutect2, varscan2
- IGDCC4 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61536696, COSV61538238; called by muse, mutect2, varscan2
- IMMP2L | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100070897, COSV100071348; called by muse, mutect2, varscan2
- INVS | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV99317575; called by muse, mutect2, varscan2
- ITGA8 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100959235; called by muse, mutect2, varscan2
- KAT14 | c.2077G>T p.D693Y | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100890079; called by muse, mutect2, varscan2
- KAZN | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs1217076482, COSV101055780; called by muse, mutect2, varscan2
- KCNB1 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100870472; called by muse, mutect2, varscan2
- KIAA0319L | c.3010G>A p.E1004K | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100357401; called by muse, mutect2, varscan2
- KIAA1191 | c.915C>G p.F305L | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100055436; called by muse, mutect2
- KIF5A | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs1398974670, COSV54059351; called by muse, mutect2, varscan2
- KIF7 | c.3111G>A p.E1037= | Splice Region (SNP) | VAF 17/84 reads (20%) | catalogued as COSV99176535; called by muse, mutect2, varscan2
- KLHL17 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.925); catalogued as COSV100497968, COSV100498031; called by muse, mutect2, varscan2
- KLHL30 | c.558C>A p.D186E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1310859678, COSV100014337; called by muse, mutect2
- LILRA1 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as rs771954481, COSV99251925; called by muse, mutect2, varscan2
- LRIG2 | c.2738C>G p.S913C | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100743378; called by muse, mutect2, varscan2
- LRP1B | c.4549C>A p.Q1517K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV101257477; called by muse, mutect2, varscan2
- MAGED1 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs782441648, COSV58514841; called by muse, mutect2, varscan2
- MAP1A | c.7414C>T p.R2472W | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs761071477, COSV55810637; called by muse, mutect2, varscan2
- MAP3K11 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100482533, COSV58422026; called by muse, mutect2, varscan2
- MAPK12 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753162308, COSV99299383; called by muse, mutect2, varscan2
- MDGA2 | c.2194G>A p.D732N (on ENST00000399232 / NM_001113498.2; = p.D434N on NM_182830.4) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100637282, COSV62094267; called by muse, mutect2, varscan2
- MEGF8 | c.7036G>A p.E2346K (on ENST00000251268 / NM_001271938.2; = p.E2279K on NM_001410.3) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.949); catalogued as rs1314672093, COSV99236511; called by muse, mutect2, varscan2
- MNAT1 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV54186984; called by muse, mutect2, varscan2
- MOS | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.426); catalogued as COSV100322837; called by muse, mutect2, varscan2
- MRGPRX4 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV58590197; called by muse, mutect2
- MUC16 | c.24209C>T p.S8070F | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV101200014; called by muse, mutect2, varscan2
- MUC17 | c.5330G>A p.S1777N | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.19); catalogued as COSV100073412; called by muse, mutect2, varscan2
- MUC5B | c.11015C>A p.P3672H | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV101500373; called by muse, mutect2, varscan2
- MYH2 | c.4822G>A p.D1608N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1428350110, COSV99820216; called by muse, mutect2, varscan2
- MYO9A | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.345); catalogued as rs1171736981, COSV100613592; called by muse, mutect2, varscan2
- N4BP2 | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 36/84 reads (43%) | catalogued as COSV54701993; called by muse, mutect2, varscan2
- NADSYN1 | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100034516; called by muse, mutect2, varscan2
- NCAPD2 | c.2858G>A p.R953Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.487); catalogued as rs949516994, COSV100217208; called by muse, mutect2, varscan2
- NLRP1 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs373530609; called by muse, mutect2, varscan2
- NLRP12 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs370612027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOS3 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs765169676, COSV52486396, COSV52492850, COSV52495663; called by muse, mutect2, varscan2
- NOX3 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as COSV50151545; called by muse, mutect2, varscan2
- NOX4 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 33/102 reads (32%) | catalogued as rs1461642703, COSV54448060; called by muse, mutect2, varscan2
- NRXN3 | c.2149C>T p.R717* (on ENST00000335750 / NM_001330195.2; = p.R344* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as COSV59813684; called by muse, mutect2, varscan2
- ORC3 | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | catalogued as COSV57644772; called by muse, mutect2, varscan2
- PCDHA11 | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as COSV100250688; called by muse, mutect2
- PCDHGA10 | c.1235G>C p.R412T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.014); catalogued as COSV99538913; called by muse, mutect2, varscan2
- PCDHGA6 | c.989G>C p.R330T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.05); catalogued as COSV54017782; called by muse, mutect2, varscan2
- PCDHGA6 | c.1123G>C p.D375H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99538910; called by muse, mutect2, varscan2
- PCDHGC4 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99340279; called by muse, mutect2, varscan2
- PDSS2 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV100941769; called by muse, mutect2, varscan2
- PDZRN4 | c.2422G>T p.E808* (on ENST00000402685 / NM_001164595.2; = p.E550* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100114564; called by muse, mutect2, varscan2
- PGC | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57824330; called by muse, mutect2, varscan2
- PIAS1 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV99986806; called by muse, mutect2, varscan2
- PIK3R6 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100266530; called by muse, mutect2, varscan2
- PLCH2 | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 28/110 reads (25%) | catalogued as rs778675146, COSV99616408; called by muse, mutect2, varscan2
- PLXNA4 | c.2594C>T p.P865L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs764802046, COSV100324778, COSV58108478; called by muse, varscan2
- POLQ | c.6698C>T p.S2233L | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV51744948; called by muse, mutect2, varscan2
- PORCN | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); catalogued as rs148060082, COSV58226460; called by muse, mutect2, varscan2
- PRDM15 | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.922); catalogued as COSV99520126; called by muse, mutect2, varscan2
- PRDX4 | c.665G>A p.G222D | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101028675; called by muse, mutect2, varscan2
- PTPN12 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50358448, COSV99950375; called by muse, mutect2, varscan2
- PTPN4 | c.2679G>T p.M893I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV99750307; called by muse, mutect2, varscan2
- PTPRE | c.708G>C p.L236F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV99617965; called by muse, mutect2, varscan2
- PVR | c.1095C>G p.F365L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.214); catalogued as COSV51822793, COSV99495809; called by muse, mutect2, varscan2
- RABGEF1 | c.156G>A p.W52* (on ENST00000439720 / NM_001287061.2; = p.W39* on NM_014504.3 and 29 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/92 reads (22%) | catalogued as rs1213630925, COSV99534842; called by muse, mutect2, varscan2
- RASGRF2 | c.1222G>T p.E408* | Nonsense Mutation (SNP) | VAF 30/153 reads (20%) | catalogued as COSV54124625, COSV99429296; called by muse, mutect2, varscan2
- RAVER1 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as rs562246379, COSV99532737; called by muse, mutect2, varscan2
- RBM10 | c.1953T>C p.I651= | Splice Region (SNP) | VAF 90/200 reads (45%) | catalogued as COSV100237853; called by muse, mutect2, varscan2
- RIN1 | c.1922C>T p.S641F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100254681; called by muse, mutect2, varscan2
- SCN7A | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1449435511, COSV101313242; called by muse, mutect2, varscan2
- SCO2 | c.703G>A p.G235S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs777327176, COSV99329563; called by muse, mutect2, varscan2
- SLC15A4 | c.1042C>T p.H348Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99903603; called by mutect2, varscan2
- SLC25A13 | c.690G>A p.M230I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as COSV99673667; called by muse, mutect2, varscan2
- SLC7A11 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99762901, COSV99763183; called by muse, mutect2, varscan2
- SLF1 | c.2004C>G p.F668L | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV99475976, COSV99476097; called by muse, mutect2, varscan2
- SLITRK6 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 66/99 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.378); catalogued as COSV101233237; called by muse, mutect2, varscan2
- SORL1 | c.1240T>A p.F414I | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.61); PolyPhen benign (0.047); catalogued as COSV99494019; called by muse, mutect2, varscan2
- SPON1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100115911; called by muse, mutect2, varscan2
- SPTAN1 | c.6391G>A p.E2131K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.6); PolyPhen benign (0.049); catalogued as rs755273355, COSV100823604; called by muse, mutect2, varscan2
- STK36 | c.1390G>T p.G464C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV99831451; called by muse, mutect2, varscan2
- SYNE1 | c.10280C>T p.T3427M (on ENST00000367255 / NM_182961.4; = p.T3434M on NM_033071.3) | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV54931325; called by muse, mutect2, varscan2
- SYNE3 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs376779070, COSV62077729; called by muse, mutect2, varscan2
- SYT17 | c.445A>T p.N149Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100810733; called by muse, mutect2, varscan2
- TATDN2 | c.2195C>T p.T732M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1229635528, COSV55053888; called by muse, mutect2, varscan2
- TCOF1 | c.1417G>A p.E473K (on ENST00000377797 / NM_001135243.1; = p.E396K on NM_000356.4) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.391); catalogued as rs1292320235, COSV100077495; called by muse, mutect2, varscan2
- TEKT4 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs558971848, COSV99726400; called by muse, mutect2, varscan2
- TLCD1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as rs1444293836, COSV52044917; called by muse, mutect2, varscan2
- TMEM131L | c.3496G>A p.E1166K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.291); catalogued as COSV99547474; called by muse, mutect2, varscan2
- TMEM132D | c.2344C>T p.R782W | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768253141, COSV67160690; called by muse, mutect2, varscan2
- TP63 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53217852; called by muse, mutect2
- TPSAB1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.037); catalogued as rs757030119, COSV58783040; called by muse, mutect2, varscan2
- TRAF3 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs992627058, COSV100693598; called by muse, mutect2, varscan2
- TRIM16 | c.1639G>C p.D547H | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV100371886; called by muse, mutect2, varscan2
- TRIM28 | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV53401061; called by muse, mutect2, varscan2
- TRIM33 | c.3079G>A p.D1027N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs940733491, COSV100635386; called by muse, mutect2, varscan2
- UBE4A | c.1446G>A p.M482I (on ENST00000252108 / NM_001204077.2; = p.M489I on NM_004788.4) | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99348240; called by muse, mutect2, varscan2
- UNC13B | c.2314G>A p.D772N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs779807142, COSV101036714; called by muse, mutect2, varscan2
- VCAN | c.4450G>A p.E1484K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as COSV99425893; called by muse, mutect2, varscan2
- VSX2 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.715); catalogued as COSV56218471; called by muse, mutect2, varscan2
- WWC2 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV100968321; called by muse, mutect2, varscan2
- XIRP2 | c.6206C>T p.T2069I (on ENST00000628543; = p.T2244I on NM_152381.6) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV54730280, COSV99743218; called by muse, mutect2, varscan2
- XRCC3 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100721287; called by muse, mutect2, varscan2
- ZBTB33 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.335); catalogued as rs376833183, COSV58532954; called by muse, mutect2, varscan2
- ZNF226 | c.1309C>A p.H437N | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100335153; called by muse, mutect2, varscan2
- ZNF320 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as rs765248150, COSV67088412; called by muse, mutect2, varscan2
- ZNF468 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV99700590; called by muse, mutect2, varscan2
- ZNF468 | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); catalogued as COSV54694355, COSV99700591; called by muse, mutect2, varscan2
- ZNF808 | c.886T>G p.F296V | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100707959; called by muse, mutect2, varscan2
- ZNF831 | c.2780G>C p.R927T | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV100925971, COSV100926045; called by muse, mutect2, varscan2
- ZNF831 | c.3115G>C p.E1039Q | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100926046, COSV64043315; called by muse, mutect2, varscan2
- ZRANB2 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.099); catalogued as COSV99639392; called by muse, mutect2, varscan2
- CASP8AP2 | c.3031G>A p.E1011K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DNAJC19 | c.220A>T p.N74Y | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2
- PLCZ1 | c.1589dup p.N530Kfs*4 | Frame Shift Ins (INS) | VAF 20/78 reads (26%) | called by mutect2, varscan2
- RNF215 | c.1087_1092del p.P363_L364del | In Frame Del (DEL) | VAF 9/55 reads (16%) | called by mutect2, pindel, varscan2
- TBC1D12 | c.1351del p.E451Kfs*8 | Frame Shift Del (DEL) | VAF 13/79 reads (16%) | called by mutect2, pindel, varscan2
- USP16 | c.2155del p.I719Sfs*2 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- ZNF772 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.011); called by muse, mutect2
- AC068580.4 | c.900C>G p.L300= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV99362405; called by muse, mutect2, varscan2
- ADAM29 | c.348C>T p.L116= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs1406450627, COSV100822025, COSV63663486; called by muse, mutect2, varscan2
- ALG9 | c.603G>A p.L201= | Silent (SNP) | VAF 24/30 reads (80%) | catalogued as COSV101211903; called by muse, mutect2, varscan2
- ALPL | c.1380C>T p.A460= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs371984578, COSV100876131; called by muse, mutect2, varscan2
- ARHGAP22 | c.132G>A p.L44= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99985320; called by muse, mutect2, varscan2
- BAMBI | c.63G>A p.V21= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs768887447, COSV100977503; called by muse, mutect2, varscan2
- CDC73 | c.21C>T p.V7= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs769522707, COSV100813882; called by muse, mutect2, varscan2
- CDSN | c.696C>T p.I232= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV52537217; called by muse, mutect2, varscan2
- CHD1 | c.1977C>T p.F659= | Silent (SNP) | VAF 54/142 reads (38%) | catalogued as COSV99399478; called by muse, mutect2, varscan2
- CLEC4M | c.414G>A p.E138= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as rs77318248, COSV99940584; called by muse, varscan2
- CNNM1 | c.2766G>A p.L922= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV100763873; called by muse, mutect2, varscan2
- COBL | c.2115C>G p.L705= | Silent (SNP) | VAF 16/20 reads (80%) | catalogued as COSV99472730; called by muse, mutect2, varscan2
- CTLA4 | c.372G>A p.T124= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs372929906; ClinVar: likely benign; called by muse, mutect2, varscan2
- DCLRE1A | c.2733C>T p.L911= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV100800377; called by muse, mutect2, varscan2
- DENND5A | c.231C>T p.V77= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100064731; called by muse, mutect2, varscan2
- DLG5 | c.1047G>A p.L349= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100967505; called by muse, mutect2, varscan2
- DPH1 | c.741C>T p.P247= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs369593878; called by muse, varscan2
- DYNC2I2 | c.936C>T p.F312= | Silent (SNP) | VAF 25/36 reads (69%) | catalogued as rs570806137, COSV100823758, COSV63987085; called by muse, mutect2, varscan2
- FAT2 | c.4146C>T p.F1382= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as COSV55827493, COSV99942965; called by muse, mutect2, varscan2
- GALNT7 | c.1212C>T p.L404= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV53927855; called by muse, mutect2, varscan2
- GPR89A | c.444C>T p.S148= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100572452; called by mutect2, varscan2
- GRIPAP1 | c.354G>A p.K118= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV100904294; called by muse, mutect2, varscan2
- HNRNPM | c.867C>T p.F289= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as rs1277156319, COSV100335195; called by muse, mutect2, varscan2
- HSPBAP1 | c.369C>T p.F123= | Silent (SNP) | VAF 35/172 reads (20%) | catalogued as COSV100063446; called by muse, mutect2, varscan2
- INPP1 | c.1134G>A p.R378= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100487224; called by muse, mutect2, varscan2
- KERA | c.1032C>T p.F344= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV99899450; called by muse, mutect2, varscan2
- KRTAP11-1 | c.321C>T p.V107= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs756066923, COSV100190648; called by muse, mutect2, varscan2
- LMAN2 | c.162C>G p.L54= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as rs777847709, COSV57425039; called by muse, mutect2, varscan2
- LMAN2 | c.69C>G p.L23= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as COSV100288389; called by muse, mutect2, varscan2
- MED10 | c.265C>T p.L89= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs776314245, COSV99740296; called by muse, mutect2, varscan2
- MEGF8 | c.1308G>A p.L436= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV99236506; called by muse, mutect2, varscan2
- MTIF2 | c.2058C>T p.V686= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV99703180; called by muse, mutect2, varscan2
- MUC16 | c.25173G>A p.T8391= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as rs373598114; called by muse, mutect2, varscan2
- MUC20 | c.2016G>A p.P672= | Silent (SNP) | VAF 12/162 reads (7%) | catalogued as rs762362567, COSV100291197; called by muse, mutect2
- MYPOP | c.1179C>T p.R393= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs138971632, COSV56192853; called by muse, mutect2, varscan2
- NCDN | c.753A>T p.T251= | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as COSV100357402; called by muse, mutect2, varscan2
- OR10AG1 | c.342C>T p.Y114= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs752641726, COSV100400044; called by muse, mutect2, varscan2
- OR5L2 | c.240G>A p.K80= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs375385745, COSV101004275, COSV65725392; called by muse, mutect2, varscan2
- PCDH17 | c.2172C>A p.I724= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100931675; called by muse, mutect2, varscan2
- PCDHGA10 | c.843G>A p.V281= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99538911; called by muse, mutect2, varscan2
- PLA2G2F | c.252C>T p.F84= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as rs201534275, COSV64280007; called by muse, mutect2, varscan2
- POLR1B | c.423G>A p.V141= | Silent (SNP) | VAF 15/148 reads (10%) | catalogued as COSV99637747; called by muse, mutect2, varscan2
- PRMT6 | c.1098G>A p.E366= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV100791198; called by muse, mutect2, varscan2
- PRPH | c.1398T>C p.S466= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV99141990; called by muse, mutect2, varscan2
- PTGDS | c.60G>A p.L20= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV99811865; called by muse, mutect2, varscan2
- PUF60 | c.1596C>T p.L532= (on ENST00000526683 / NM_001362896.2; = p.L515= on NM_014281.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as rs772030514, COSV100253385; called by muse, mutect2, varscan2
- RNF150 | c.732C>T p.N244= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100153507; called by muse, mutect2, varscan2
- RNH1 | c.462C>T p.L154= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100596754; called by muse, mutect2, varscan2
- RTN1 | c.1329G>A p.S443= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as rs756584587, COSV99955777; called by muse, mutect2, varscan2
- SEZ6 | c.525A>G p.T175= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV100253128; called by muse, mutect2, varscan2
- SH2D1A | c.45C>T p.T15= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100758305; called by muse, mutect2, varscan2
- SLC12A4 | c.2814G>A p.Q938= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV99863075; called by muse, mutect2, varscan2
- SLCO1C1 | c.375C>T p.L125= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs17852030, COSV99859168; called by muse, mutect2, varscan2
- ST8SIA5 | c.624G>A p.T208= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs375006260; called by muse, mutect2, varscan2
- STKLD1 | c.1260G>A p.L420= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV64242158; called by muse, mutect2, varscan2
- SYNE2 | c.19701G>A p.L6567= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV100647745, COSV59952022; called by muse, mutect2, varscan2
- TARS2 | c.627C>T p.F209= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as COSV100945987; called by muse, mutect2, varscan2
- TASOR2 | c.3993C>T p.L1331= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100050528; called by muse, mutect2, varscan2
- TBC1D10A | c.270C>T p.L90= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs747211182, COSV53164336; called by muse, mutect2, varscan2
- TBK1 | c.465C>T p.L155= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as rs1276287976, COSV100538172; called by muse, mutect2
- TCIRG1 | c.39C>G p.V13= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV55837345, COSV99693401; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.180C>T p.I60= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV100925316; called by muse, mutect2, varscan2
- TUBB | c.852C>T p.L284= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV100013373; called by muse, mutect2, varscan2
- TUBGCP6 | c.2385C>T p.L795= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99955596; called by muse, mutect2, varscan2
- URGCP | c.1776G>C p.L592= (on ENST00000453200 / NM_001077663.3; = p.L583= on NM_017920.4) | Silent (SNP) | VAF 54/70 reads (77%) | catalogued as COSV99787369; called by muse, mutect2, varscan2
- URGCP | c.1482G>A p.L494= (on ENST00000453200 / NM_001077663.3; = p.L485= on NM_017920.4) | Silent (SNP) | VAF 21/30 reads (70%) | catalogued as COSV99787372; called by muse, mutect2, varscan2
- USH2A | c.12063G>A p.V4021= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100235295; called by muse, mutect2, varscan2
- USP2 | c.1510C>A p.R504= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV52729218, COSV99489683; called by mutect2, varscan2
- WDR24 | c.192G>A p.E64= (on ENST00000248142; = p.E2= on NM_032259.4) | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as rs763002818, COSV99556629; called by muse, mutect2, varscan2
- ZNF787 | c.546C>T p.R182= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99555560; called by muse, varscan2
- ZXDB | c.555C>T p.L185= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV100885934; called by muse, mutect2, varscan2
- C1orf220 | n.539G>A | RNA (SNP) | VAF 31/56 reads (55%) | catalogued as rs369861869; called by muse, mutect2, varscan2
- CARMIL3 | chr14:24048222 C>T | 5'Flank (SNP) | VAF 40/148 reads (27%) | catalogued as rs371746643; called by muse, mutect2
- LRMDA | c.131+113969C>T | Intron (SNP) | VAF 16/62 reads (26%) | catalogued as COSV101130148; called by muse, mutect2, varscan2
- NEK1 | c.1666-490G>A | Intron (SNP) | VAF 25/53 reads (47%) | catalogued as rs766095567, COSV101455691; called by muse, mutect2, varscan2
- NRXN1 | c.3365-109910G>A | Intron (SNP) | VAF 11/22 reads (50%) | catalogued as rs773983971, COSV100455289; called by muse, mutect2, varscan2
- SNORD115-11 | n.31G>A | RNA (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2, varscan2
